Somatic mutation profile of tumor specimen TCGA-29-1778-01A (aliquot TCGA-29-1778-01A-01W-0639-09) from TCGA case TCGA-29-1778, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 77.1 years (28,147 days).
Specimen TCGA-29-1778-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6182516b-d843-45ad-8485-086a1f84b207.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-29-1778-10A (Blood Derived Normal), aliquot TCGA-29-1778-10A-01W-0639-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ef5c844e-4b23-45c5-ac68-e41c0f61748a

The open-access MAF lists 55 somatic variants for this specimen: 37 protein-altering or splice-affecting, 18 silent.
By variant classification: Missense Mutation 30, Silent 18, Nonsense Mutation 3, Frame Shift Del 2, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 40/60 reads (67%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AGA | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV52806098; called by muse, mutect2, varscan2
- ANKLE2 | c.1438C>A p.L480I | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61709134; called by muse, mutect2, varscan2
- BZW2 | c.49C>T p.R17W | Missense Mutation (SNP) | VAF 28/153 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as COSV51754877; called by muse, mutect2, varscan2
- CCIN | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.047); catalogued as rs566301509, COSV58724480; called by muse, mutect2, varscan2
- CROT | c.997A>G p.M333V | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as rs536903511, COSV58973936; called by muse, mutect2, varscan2
- FAM160B1 | c.2237A>C p.E746A | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV65087939; called by muse, mutect2, varscan2
- FLNB | c.6655C>T p.R2219W | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1452080639, COSV99911506; called by muse, mutect2
- GABRB3 | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 37/173 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as COSV54661237; called by muse, mutect2, varscan2
- GRIA1 | c.1033C>T p.R345* | Nonsense Mutation (SNP) | VAF 10/197 reads (5%) | catalogued as COSV53612160, COSV53612270; called by muse, mutect2
- HBQ1 | c.392G>A p.S131N | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV52265603; called by muse, mutect2
- IFT172 | c.1015A>G p.K339E | Missense Mutation (SNP) | VAF 353/513 reads (69%) | SIFT deleterious (0.01); PolyPhen benign (0.379); catalogued as COSV53132868; called by muse, mutect2, varscan2
- KIAA0408 | c.1303A>G p.N435D | Missense Mutation (SNP) | VAF 100/198 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV64106297; called by muse, mutect2, varscan2
- KMT2A | c.4438A>G p.K1480E | Missense Mutation (SNP) | VAF 55/71 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as COSV63285038; called by muse, mutect2, varscan2
- MAP1LC3C | c.343G>T p.V115L | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV100606370; called by muse, mutect2
- MAP4 | c.2514G>T p.K838N | Missense Mutation (SNP) | VAF 34/712 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99274590; called by muse, mutect2
- MMP12 | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV58259645; called by muse, mutect2, varscan2
- MRGPRX4 | c.524C>T p.T175M | Missense Mutation (SNP) | VAF 69/189 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.559); catalogued as rs766715484, COSV58590392; called by muse, mutect2, varscan2
- NCEH1 | c.1279C>T p.P427S (on ENST00000538775; = p.P387S on NM_020792.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/188 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56434188; called by muse, mutect2, varscan2
- NRCAM | c.1464G>A p.W488* (on ENST00000379028 / NM_001371124.1; = p.W482* on NM_005010.4 and 21 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 36/167 reads (22%) | catalogued as COSV104418239, COSV61035332; called by muse, mutect2, varscan2
- NUAK2 | c.570+1G>A p.X190_splice | Splice Site (SNP) | VAF 37/66 reads (56%) | catalogued as COSV65681303; called by muse, mutect2, varscan2
- PHEX | c.670C>A p.Q224K | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.284); catalogued as rs948246694, CM056036, COSV101039359; called by muse, mutect2
- PHLDB2 | c.107A>G p.E36G | Missense Mutation (SNP) | VAF 76/587 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.115); catalogued as COSV67310593; called by muse, mutect2, varscan2
- PKDREJ | c.5987G>T p.S1996I | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99478331; called by muse, mutect2
- RBM47 | c.354C>G p.Y118* | Nonsense Mutation (SNP) | VAF 22/38 reads (58%) | catalogued as COSV55934070; called by muse, mutect2, varscan2
- SDF4 | c.527T>G p.L176R | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV99767318; called by muse, mutect2
- SNX17 | c.1172G>T p.S391I | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.511); catalogued as COSV52007468; called by muse, mutect2, varscan2
- SPIN4 | c.375T>A p.H125Q | Missense Mutation (SNP) | VAF 5/138 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); catalogued as COSV100633295; called by muse, mutect2
- SRPX | c.708G>T p.K236N | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.562); catalogued as COSV100655863, COSV59438850; called by muse, mutect2
- USH2A | c.14970C>A p.T4990= | Splice Region (SNP) | VAF 150/239 reads (63%) | catalogued as COSV56360391; called by muse, mutect2, varscan2
- USP43 | c.2396C>T p.A799V | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as COSV53301697; called by muse, mutect2, varscan2
- ZFP3 | c.1441G>C p.E481Q | Missense Mutation (SNP) | VAF 7/148 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV100603663; called by muse, mutect2
- ZNF564 | c.173A>C p.N58T | Missense Mutation (SNP) | VAF 12/281 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.056); catalogued as COSV100213009; called by muse, mutect2
- ZNF718 | c.1171G>A p.G391R | Missense Mutation (SNP) | VAF 50/102 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV68140383; called by muse, mutect2, varscan2
- PCDHGB5 | c.1408G>A p.V470I | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.57); called by muse, mutect2
- VPS13B | c.4736_4737del p.V1579Gfs*14 | Frame Shift Del (DEL) | VAF 20/194 reads (10%) | called by pindel, varscan2
- ZNF800 | c.234_235del p.F78Lfs*10 | Frame Shift Del (DEL) | VAF 57/279 reads (20%) | called by mutect2, pindel, varscan2
- ADNP2 | c.744A>G p.R248= | Silent (SNP) | VAF 39/222 reads (18%) | catalogued as rs201578344, COSV51538196; called by muse, mutect2, varscan2
- ANKAR | c.1983C>T p.I661= | Silent (SNP) | VAF 26/155 reads (17%) | catalogued as rs772659771, COSV55611996; called by muse, mutect2, varscan2
- ANKRD28 | c.402C>T p.N134= | Silent (SNP) | VAF 113/319 reads (35%) | catalogued as rs758870866, COSV67517769; called by muse, mutect2, varscan2
- C17orf98 | c.117G>A p.A39= | Silent (SNP) | VAF 6/40 reads (15%) | called by muse, mutect2, varscan2
- DRG2 | c.702C>A p.G234= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV99854778; called by muse, mutect2
- ENOX2 | c.915C>T p.N305= (on ENST00000338144 / NM_001382520.1; = p.N276= on NM_006375.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 68/268 reads (25%) | catalogued as rs775886338, COSV57650624; called by muse, varscan2
- EPB41L4B | c.363G>C p.V121= | Silent (SNP) | VAF 26/184 reads (14%) | catalogued as COSV101000544, COSV65796803; called by muse, mutect2, varscan2
- FAM153B | c.321G>A p.K107= (on ENST00000253490; = p.K30= on NM_001265615.1) | Silent (SNP) | VAF 9/125 reads (7%) | catalogued as rs1356304948, COSV99498703; called by muse, mutect2, varscan2
- GRIN3A | c.3175C>A p.R1059= | Silent (SNP) | VAF 58/141 reads (41%) | catalogued as rs145862529, COSV62455621; called by muse, mutect2, varscan2
- ICAM4 | c.813G>A p.A271= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as rs1376788546, COSV53424655; called by muse, mutect2, varscan2
- IP6K3 | c.720G>A p.A240= | Silent (SNP) | VAF 7/71 reads (10%) | catalogued as rs746542544, COSV99539557; called by mutect2, varscan2
- ITPRIPL2 | c.1542C>A p.R514= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs1327064360, COSV67347541; called by muse, mutect2
- LCN9 | c.426C>T p.C142= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as rs759766790, COSV52990544; called by muse, mutect2, varscan2
- MYH4 | c.4813C>T p.L1605= | Silent (SNP) | VAF 120/163 reads (74%) | catalogued as COSV55117046, COSV55122765; called by muse, mutect2, varscan2
- NCOR2 | c.1677C>T p.D559= | Silent (SNP) | VAF 29/94 reads (31%) | catalogued as rs759827085, COSV62296999; called by muse, mutect2, varscan2
- SLC24A3 | c.237C>T p.A79= | Silent (SNP) | VAF 24/121 reads (20%) | catalogued as rs752016252, COSV60118032; called by muse, mutect2, varscan2
- UAP1 | c.600C>T p.P200= | Silent (SNP) | VAF 24/171 reads (14%) | catalogued as rs773224160, COSV54850389; called by muse, mutect2, varscan2
- ZCCHC8 | c.1731G>A p.T577= | Silent (SNP) | VAF 192/401 reads (48%) | catalogued as rs377551940; called by muse, mutect2, varscan2
